Somatic mutation profile of tumor specimen MP2PRT-PAVLTY-TMP1-A (aliquot MP2PRT-PAVLTY-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVLTY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,291 days).
Specimen MP2PRT-PAVLTY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebdfc68f-2c72-45d6-95cb-8fac943a7ea0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVLTY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVLTY-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a585f37-3cba-4a1e-a524-41e29fc8eeeb

The open-access MAF lists 88 somatic variants for this specimen: 68 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 19, Nonsense Mutation 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS10 | c.196A>T p.R66W | Missense Mutation (SNP) | VAF 100/259 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780874811; called by muse, mutect2, varscan2
- CCDC18 | c.4147G>C p.E1383Q | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV100160143; called by muse, mutect2, varscan2
- CER1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 25/359 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV66602954; called by muse, mutect2
- COL4A3 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV67414968; called by muse, mutect2
- DDOST | c.592C>T p.R198* (on ENST00000415136; = p.R181* on NM_005216.5) | Nonsense Mutation (SNP) | VAF 47/174 reads (27%) | catalogued as rs747589765, COSV100387146; called by muse, mutect2, varscan2
- FNDC1 | c.3790C>T p.R1264C | Missense Mutation (SNP) | VAF 232/822 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs370423767, COSV99794936; called by muse, mutect2
- FOXD2 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 192/650 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs1350348728; called by muse, mutect2, varscan2
- HAGHL | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 118/325 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV52405908, COSV99284623; called by muse, mutect2, varscan2
- HUWE1 | c.4477G>A p.D1493N | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as COSV99472055; called by muse, mutect2
- JPH3 | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 127/391 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs778517943; called by muse, mutect2, varscan2
- KMT2D | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM122087, CM146860, COSV99977967; called by muse, mutect2
- KRT9 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 87/324 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs767325538, COSV55854102; called by muse, mutect2, varscan2
- LATS1 | c.2494G>C p.D832H | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53600559; called by muse, mutect2, varscan2
- MTBP | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.025); catalogued as COSV100011950, COSV100012652, COSV59966168; called by muse, mutect2, varscan2
- MYC | c.751G>A p.D251N (on ENST00000377970; = p.D266N on NM_002467.6) | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52373566; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10A2 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV100225088; called by muse, mutect2, varscan2
- PCDH15 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV100229874, COSV57382459; called by muse, mutect2, varscan2
- RGL1 | c.1741C>G p.Q581E (on ENST00000360851 / NM_001297672.2; = p.Q616E on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755374010; called by muse, mutect2, varscan2
- RPS25 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV100548920; called by muse, mutect2, varscan2
- SIDT2 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371165317; called by muse, mutect2, varscan2
- SMG5 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 107/338 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs779846506; called by muse, mutect2, varscan2
- SMOX | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 121/437 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53863379; called by muse, mutect2, varscan2
- SPNS1 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as rs141585401; called by muse, mutect2, varscan2
- SUV39H2 | c.962G>A p.R321Q (on ENST00000354919 / NM_001193424.2; = p.R261Q on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.558); catalogued as rs1331333840, COSV100543237; called by muse, mutect2, varscan2
- TMEM132D | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs12816729, COSV70598854; called by muse, mutect2
- UNC80 | c.5447C>T p.S1816L | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV55907869; called by muse, mutect2, varscan2
- USP37 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV51443357; called by muse, mutect2, varscan2
- ADAM7 | c.1864C>G p.L622V | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARX | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 147/583 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ASCL2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 45/717 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- C9orf40 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 21/700 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2
- CDKL5 | c.217G>C p.V73L | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CDRT15L2 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP120 | c.2365G>C p.D789H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- CFAP45 | c.1199G>C p.R400T | Missense Mutation (SNP) | VAF 96/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COL21A1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.346); called by muse, mutect2
- DEF8 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 35/516 reads (7%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2
- DNAJB13 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DRD3 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- DSC2 | c.1755C>A p.C585* | Nonsense Mutation (SNP) | VAF 12/406 reads (3%) | called by muse, mutect2
- FBXO27 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FHAD1 | c.2897-1G>A p.X966_splice | Splice Site (SNP) | VAF 46/196 reads (23%) | called by mutect2, varscan2
- FIGNL2 | c.1431C>G p.F477L | Missense Mutation (SNP) | VAF 105/340 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ISOC1 | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 32/574 reads (6%) | called by muse, mutect2
- LIG1 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 105/337 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPKAP1 | c.1090G>C p.E364Q (on ENST00000265960 / NM_001006617.3; = p.E328Q on NM_024117.3) | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MLH3 | c.2662C>G p.Q888E | Missense Mutation (SNP) | VAF 12/355 reads (3%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2
- MTPN | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NADSYN1 | c.1262A>T p.K421M | Missense Mutation (SNP) | VAF 120/364 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- NAV3 | c.4462C>G p.Q1488E | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- PLPBP | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, varscan2
- PTCH2 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 128/437 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- REPS2 | c.1380-1G>A p.X460_splice | Splice Site (SNP) | VAF 57/199 reads (29%) | called by muse, mutect2, varscan2
- RLF | c.929C>G p.A310G | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCNN1G | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.883); called by muse, mutect2
- SERPINA11 | c.708G>C p.E236D | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TBX22 | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 177/509 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TENM2 | c.2563G>A p.E855K (on ENST00000518659 / NM_001122679.2; = p.E623K on NM_001080428.3) | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TJP2 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 76/285 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLE1 | c.403C>G p.H135D | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TLN2 | c.5266G>C p.D1756H | Missense Mutation (SNP) | VAF 124/361 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- UBA2 | c.563G>C p.W188S | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H11B | c.2319T>A p.D773E | Missense Mutation (SNP) | VAF 56/363 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZFHX3 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 41/354 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); called by muse, varscan2
- ZFP36L2 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 182/578 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZMIZ1 | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ZNF300 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); called by muse, mutect2
- ACOX1 | c.1236C>G p.V412= | Silent (SNP) | VAF 14/253 reads (6%) | called by muse, mutect2
- ANK3 | c.7035C>T p.V2345= | Silent (SNP) | VAF 79/264 reads (30%) | called by muse, mutect2, varscan2
- CLASP1 | c.618C>T p.L206= | Silent (SNP) | VAF 84/288 reads (29%) | catalogued as rs1046431225; called by muse, mutect2, varscan2
- CXorf56 | c.43C>A p.R15= | Silent (SNP) | VAF 103/350 reads (29%) | catalogued as COSV57439563; called by muse, mutect2, varscan2
- DYNC2H1 | c.8955C>G p.V2985= | Silent (SNP) | VAF 65/213 reads (31%) | catalogued as COSV62108236; called by muse, mutect2, varscan2
- GREM2 | c.330G>A p.V110= | Silent (SNP) | VAF 127/387 reads (33%) | called by muse, mutect2, varscan2
- GTF3C2 | c.462G>A p.L154= | Silent (SNP) | VAF 103/298 reads (35%) | catalogued as rs756027066; called by muse, mutect2, varscan2
- IPO9 | c.1740C>G p.L580= | Silent (SNP) | VAF 26/351 reads (7%) | catalogued as COSV64233308; called by muse, mutect2
- KCNA1 | c.669C>T p.I223= | Silent (SNP) | VAF 28/306 reads (9%) | catalogued as rs766618582, COSV66838788; called by muse, mutect2
- MAP7D2 | c.951G>A p.V317= | Silent (SNP) | VAF 19/405 reads (5%) | called by muse, mutect2
- PCNX3 | c.4443C>T p.R1481= | Silent (SNP) | VAF 82/244 reads (34%) | catalogued as rs1214382516, COSV100856308; called by muse, varscan2
- PFKFB2 | c.159C>T p.Y53= | Silent (SNP) | VAF 105/301 reads (35%) | catalogued as rs759693090, COSV65548059; called by muse, mutect2, varscan2
- PIK3R6 | c.705G>A p.Q235= | Silent (SNP) | VAF 42/591 reads (7%) | called by muse, mutect2
- POT1 | c.69C>T p.V23= | Silent (SNP) | VAF 34/178 reads (19%) | called by muse, mutect2, varscan2
- RTKN2 | c.33C>A p.L11= | Silent (SNP) | VAF 158/570 reads (28%) | catalogued as rs1399268104, COSV65681376; called by muse, mutect2, varscan2
- SLF2 | c.1779G>A p.L593= | Silent (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- VAV3 | c.237C>G p.L79= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- XPNPEP2 | c.1095C>T p.L365= | Silent (SNP) | VAF 89/367 reads (24%) | catalogued as COSV64368402; called by muse, mutect2, varscan2
- ZNF281 | c.2343C>T p.F781= | Silent (SNP) | VAF 84/274 reads (31%) | catalogued as COSV54169374; called by muse, mutect2, varscan2
- ABI3BP | c.2008+1656G>C | Intron (SNP) | VAF 52/196 reads (27%) | called by muse, mutect2, varscan2
